Somatic mutation profile of tumor specimen TCGA-EY-A2OM-01A (aliquot TCGA-EY-A2OM-01A-11D-A18P-09) from TCGA case TCGA-EY-A2OM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 55.8 years (20,398 days).
Specimen TCGA-EY-A2OM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cbc1a4c-d3dc-4f1e-9483-d61102335b2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A2OM-10A (Blood Derived Normal), aliquot TCGA-EY-A2OM-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfba61b2-1068-425d-bf61-b2d249fa5057

The open-access MAF lists 742 somatic variants for this specimen: 569 protein-altering or splice-affecting, 154 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 356, Silent 154, Frame Shift Del 149, Frame Shift Ins 20, Nonsense Mutation 19, In Frame Del 9, Splice Region 8, Intron 8, Splice Site 8, RNA 5, 5'UTR 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as rs377160065, CM075939; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 16/32 reads (50%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 38/92 reads (41%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BSCL2 | c.782dup p.I262Hfs*12 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | catalogued as rs749890533; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.4549C>T p.R1517* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs1459799356, COSV55860009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MLH1 | c.546-2A>G p.X182_splice | Splice Site (SNP) | VAF 28/90 reads (31%) | catalogued as rs267607759, CS064426, CS961615, COSV99212291; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 47/103 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as rs751284215; called by mutect2, pindel, varscan2
- ABCG1 | c.1444G>T p.G482* | Nonsense Mutation (SNP) | VAF 45/105 reads (43%) | catalogued as COSV100493712; called by muse, mutect2, varscan2
- ACAD10 | c.2713C>T p.R905* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as rs765418830, COSV58156728; called by muse, mutect2, varscan2
- ACAN | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs374211268; called by muse, mutect2, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as rs546931496; called by mutect2, pindel, varscan2
- ADAM30 | c.1865del p.N622Ifs*71 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs750058585; called by mutect2, varscan2
- ADAMTSL2 | c.125del p.G42Afs*26 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs1392373004; called by pindel, varscan2
- ADARB1 | c.1997G>A p.R666H (on ENST00000360697 / NM_001346687.2; = p.R626H on NM_001112.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100653557; called by muse, mutect2, varscan2
- ADGRL1 | c.3908C>A p.P1303H (on ENST00000340736 / NM_001008701.3; = p.P1298H on NM_014921.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100529176; called by muse, mutect2, varscan2
- ADGRV1 | c.10318A>G p.S3440G | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV101315300; called by muse, mutect2, varscan2
- ADIPOR1 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as COSV100579353; called by muse, varscan2
- ADORA2B | c.590T>C p.I197T | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs776840698, COSV100419942; called by muse, mutect2, varscan2
- AJM1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs745988535, COSV99915314; called by muse, mutect2, varscan2
- ALG12 | c.768+1del p.X256_splice | Splice Site (DEL) | VAF 26/76 reads (34%) | catalogued as rs762397075, COSV58206565; called by mutect2, pindel, varscan2
- ALMS1 | c.9913A>G p.N3305D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV100040800; called by muse, mutect2, varscan2
- ALOX12B | c.767A>C p.E256A | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV100046521; called by muse, mutect2, varscan2
- ALPG | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs772996790, COSV99779104; called by muse, varscan2
- AMPH | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768583906, COSV57761502; called by muse, mutect2, varscan2
- ANAPC1 | c.1880T>C p.F627S | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100594459; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 43/82 reads (52%) | catalogued as rs34047276; called by mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD53 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as rs782123032, COSV55537384; called by muse, mutect2, varscan2
- AP5Z1 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1291755306, COSV100803960; called by muse, mutect2, varscan2
- APP | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs200159151, COSV100695161; called by muse, mutect2, varscan2
- APPL1 | c.820A>G p.N274D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99897270; called by muse, mutect2, varscan2
- ARHGAP21 | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.079); catalogued as rs200969279, COSV100255604; called by muse, mutect2, varscan2
- ARHGAP25 | c.1340G>A p.R447Q (on ENST00000409202 / NM_001007231.3; = p.R439Q on NM_014882.3) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.902); catalogued as rs200609383; called by muse, mutect2, varscan2
- ARHGEF10 | c.2032G>A p.V678I (on ENST00000398564; = p.V653I on NM_014629.4) | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs769409907, COSV100033421; called by muse, mutect2, varscan2
- ARHGEF7 | c.667G>A p.E223K (on ENST00000375741 / NM_001113511.2; = p.E45K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99520708; called by muse, mutect2, varscan2
- ARRDC5 | c.781C>T p.R261C (on ENST00000381781; = p.R247C on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs779292048, COSV101108056; called by muse, mutect2, varscan2
- ARVCF | c.2345C>A p.T782N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV99258208; called by muse, mutect2, varscan2
- ASPHD2 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99313045; called by muse, mutect2, varscan2
- ATF3 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.482); catalogued as COSV100421931; called by muse, mutect2, varscan2
- ATG9A | c.2467G>A p.V823M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs1227788920, COSV54694655; called by muse, mutect2, varscan2
- ATG9A | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.83); catalogued as rs199900351; called by muse, mutect2, varscan2
- ATP1A1 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99814053; called by muse, mutect2, varscan2
- ATP6V1F | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as rs1466567024, COSV50799955; called by muse, mutect2, varscan2
- ATP9B | c.2836C>T p.Q946* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100302605; called by muse, mutect2, varscan2
- ATRIP | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs199783860, COSV56496815; called by muse, mutect2, varscan2
- BAZ1A | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100701077; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BMI1 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100936250; called by muse, mutect2, varscan2
- C1D | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100878156; called by muse, mutect2, varscan2
- C1S | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100196291; called by muse, mutect2, varscan2
- C3orf52 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99332210; called by muse, mutect2, varscan2
- C5 | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.197); catalogued as rs1383923973, COSV99796907; called by muse, mutect2, varscan2
- CACNA1B | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774542091, COSV99494475; called by muse, mutect2, varscan2
- CACNA1D | c.4850G>A p.R1617K (on ENST00000350061 / NM_001128840.3; = p.R1637K on NM_000720.4) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV99856242; called by muse, mutect2, varscan2
- CALCRL | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs779482907, COSV66474664; called by muse, mutect2, varscan2
- CAMTA2 | c.2337C>A p.N779K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100772286; called by muse, mutect2, varscan2
- CCAR1 | c.1952G>T p.R651L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56269025, COSV99770445; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC61 | c.1184C>T p.T395I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.308); catalogued as COSV50516747, COSV99151474; called by muse, varscan2
- CCM2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs762020337, COSV51847362; called by muse, mutect2
- CCR1 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99946593; called by muse, mutect2, varscan2
- CD109 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1213149278, COSV54649392; called by muse, mutect2
- CD244 | c.429del p.K144Rfs*32 (on ENST00000368033 / NM_001166663.2; = p.K139Rfs*32 on NM_016382.4) | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | catalogued as COSV59238303; called by mutect2, pindel, varscan2
- CD33 | c.1016A>G p.H339R | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs374286140; called by muse, mutect2, varscan2
- CDC42EP1 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113668714, COSV50757236; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs762194001; called by mutect2, varscan2
- CDC73 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072926, COSV66465222; called by muse, mutect2, varscan2
- CDH12 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1465712081, COSV66392941, COSV66421592; called by muse, mutect2, varscan2
- CDH23 | c.7893C>A p.N2631K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.794); catalogued as COSV99818243; called by muse, mutect2, varscan2
- CDHR2 | c.2363del p.G788Vfs*4 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs868286996; called by mutect2, pindel, varscan2
- CDIN1 | c.346C>T p.P116S (on ENST00000437989; = p.P18S on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs758085699, COSV57715623; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 16/40 reads (40%) | catalogued as rs375852685; called by mutect2, varscan2
- CENPH | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV99295438; called by muse, mutect2, varscan2
- CEP250 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1161290747, COSV100698681; called by muse, mutect2, varscan2
- CIC | c.319G>T p.G107* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99358703; called by muse, mutect2, varscan2
- CIC | c.2353del p.A785Pfs*139 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as rs34000070, COSV99359651; called by mutect2, pindel, varscan2
- CIITA | c.1962del p.A656Pfs*30 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as COSV60863473; called by mutect2, varscan2
- CKAP4 | c.1556C>A p.A519D | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.369); catalogued as COSV100952372; called by muse, mutect2, varscan2
- CLEC4A | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99983467; called by muse, mutect2, varscan2
- CLOCK | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.251); catalogued as COSV100011478; called by muse, mutect2, varscan2
- CNMD | c.304A>C p.K102Q | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.422); catalogued as COSV100937139; called by muse, mutect2, varscan2
- CNTN6 | c.176A>G p.H59R | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1242186303, COSV100609723; called by muse, mutect2, varscan2
- CNTRL | c.3785T>C p.L1262P | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99440726; called by muse, mutect2, varscan2
- CNTRL | c.5116C>T p.Q1706* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV99440733; called by muse, mutect2, varscan2
- COG7 | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV100207302; called by muse, mutect2, varscan2
- COL16A1 | c.264G>A p.T88= | Splice Region (SNP) | VAF 15/39 reads (38%) | catalogued as rs200053034, COSV54703949; called by muse, mutect2, varscan2
- CPB1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV99294025; called by muse, mutect2, varscan2
- CREBBP | c.6215G>A p.R2072Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as rs1476634343, COSV52114650; called by muse, mutect2, varscan2
- CST9L | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs760801440, COSV65407642, COSV65408515; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP7B1 | c.392del p.N131Ifs*4 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | catalogued as rs748480664, COSV59597772; called by mutect2, pindel, varscan2
- CYTH3 | c.1093A>G p.S365G (on ENST00000396741; = p.S364G on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.482); catalogued as COSV100083842; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 19/29 reads (66%) | catalogued as COSV99245498; called by mutect2, varscan2
- DCP1A | c.999del p.S334Afs*8 | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | catalogued as COSV99588276; called by mutect2, pindel, varscan2
- DDX3X | c.1612G>C p.G538R (on ENST00000399959; = p.G539R on NM_001356.5) | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67864636; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs778036194; called by mutect2, varscan2
- DENND1C | c.90del p.I31Sfs*81 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs757060526; called by mutect2, pindel, varscan2
- DEPTOR | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs200382706; called by muse, mutect2, varscan2
- DGKK | c.1579G>A p.G527S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.793); catalogued as COSV101052844; called by muse, mutect2
- DGKZ | c.1636-2A>G p.X546_splice (on ENST00000454345 / NM_001105540.2; = p.X358_splice on NM_003646.4) | Splice Site (SNP) | VAF 27/53 reads (51%) | catalogued as COSV100550914; called by muse, mutect2, varscan2
- DIP2C | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99789545; called by muse, mutect2, varscan2
- DLG5 | c.1251G>T p.E417D | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100967179; called by muse, mutect2, varscan2
- DMRT2 | c.1180A>T p.M394L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV99425877; called by muse, mutect2, varscan2
- DNAH2 | c.12815G>A p.R4272Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs1182032019, COSV101208932; called by muse, mutect2, varscan2
- DNAH9 | c.7596T>G p.Y2532* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99303144; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 33/61 reads (54%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK6 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); catalogued as rs536817277, COSV99624387; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 26/48 reads (54%) | catalogued as rs35482889; called by mutect2, varscan2
- DPY19L2 | c.620T>C p.M207T | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100116401, COSV60544949; called by muse, mutect2, varscan2
- DRAXIN | c.170A>G p.H57R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99610489; called by muse, mutect2, varscan2
- DSP | c.8377A>G p.M2793V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV100672832; called by muse, mutect2, varscan2
- DTX4 | c.1527dup p.G510Rfs*66 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | catalogued as rs762133243; called by mutect2, varscan2
- EDRF1 | c.3277+1G>A p.X1093_splice (on ENST00000356792 / NM_001202438.2; = p.X1059_splice on NM_015608.2) | Splice Site (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100523104; called by muse, mutect2, varscan2
- EGFR | c.833A>G p.D278G | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.127); catalogued as COSV99285698; called by muse, mutect2, varscan2
- EHD4 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757538412, COSV55005528; called by muse, mutect2, varscan2
- EIF5A2 | c.67T>G p.S23A | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV99858504; called by muse, mutect2, varscan2
- ELSPBP1 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100353447; called by muse, mutect2
- EP400 | c.3869G>A p.C1290Y | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100200082, COSV57786866; called by muse, mutect2, varscan2
- EPG5 | c.5704dup p.Y1902Lfs*2 | Frame Shift Ins (INS) | VAF 8/23 reads (35%) | catalogued as rs760768451; called by mutect2, varscan2
- EPHA10 | c.2604del p.R869Gfs*10 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs1449193125; called by mutect2, pindel, varscan2
- EPHA8 | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs764652650, COSV51297479; called by muse, mutect2, varscan2
- ERBB4 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs372631205; called by muse, mutect2, varscan2
- ERGIC1 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.285); catalogued as COSV100442573; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 90/111 reads (81%) | catalogued as rs775950025; called by mutect2, varscan2
- ESRP2 | c.995C>T p.A332V (on ENST00000565858 / NM_001365264.1; = p.A322V on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752955291, COSV52174757; called by muse, mutect2, varscan2
- ESRRB | c.472T>C p.C158R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99834643; called by muse, mutect2, varscan2
- ETS2 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100711140; called by muse, mutect2, varscan2
- EVL | c.253C>T p.R85C (on ENST00000402714 / NM_001330221.2; = p.R87C on NM_016337.3) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs146349659; called by muse, mutect2, varscan2
- EXOSC10 | c.759G>T p.M253I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100442037; called by muse, mutect2, varscan2
- FAM183A | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100088155; called by muse, mutect2
- FAM184A | c.900A>C p.K300N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs933277421, COSV100137255; called by muse, mutect2, varscan2
- FAM207A | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52421527, COSV99384182; called by muse, mutect2, varscan2
- FAM47C | c.761A>G p.Q254R | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs879995795, COSV63728524; called by muse, mutect2, varscan2
- FAM47C | c.3095C>T p.S1032L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs782553697, COSV63726515; called by muse, mutect2
- FARSA | c.437del p.G146Dfs*14 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs746493788; called by mutect2, pindel, varscan2
- FAT2 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99941315; called by muse, mutect2, varscan2
- FAT3 | c.5744C>T p.P1915L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.442); catalogued as rs1295702759, COSV99960077; called by muse, mutect2, varscan2
- FBXO46 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as COSV100479869; called by muse, mutect2, varscan2
- FCGBP | c.4421G>A p.C1474Y | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587719993, COSV99660349; called by muse, mutect2, varscan2
- FITM2 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV101201970; called by muse, mutect2, varscan2
- FMR1 | c.577C>A p.R193S | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.199); catalogued as COSV99502848, COSV99502862; called by muse, mutect2, varscan2
- FOXD4 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV100070512; called by muse, mutect2, varscan2
- FOXD4L3 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.368); catalogued as COSV100730956; called by mutect2, varscan2
- FOXP3 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.727); catalogued as COSV100873063; called by muse, mutect2, varscan2
- FPR3 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100200507; called by muse, mutect2, varscan2
- FRMD3 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs777625741, COSV58461057; called by muse, mutect2, varscan2
- FSD1 | c.801G>A p.A267= | Splice Region (SNP) | VAF 15/45 reads (33%) | catalogued as rs144315014; called by muse, mutect2, varscan2
- GALNT5 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV99374730; called by muse, mutect2, varscan2
- GALR1 | c.557T>C p.F186S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100231614; called by muse, mutect2, varscan2
- GAS6 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as rs1197317332, COSV100580938; called by muse, mutect2, varscan2
- GGH | c.577A>G p.N193D | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV52649257; called by muse, mutect2, varscan2
- GLB1L2 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as rs745922862, COSV100335031; called by muse, mutect2, varscan2
- GLT1D1 | c.217+2T>C p.X73_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as rs1276939790, COSV55878962, COSV99895649; called by muse, mutect2, varscan2
- GNL3L | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs141166134, COSV60576523; called by muse, mutect2, varscan2
- GOLIM4 | c.1891del p.R631Gfs*87 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs1210775698; called by mutect2, pindel, varscan2
- GP5 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.395); catalogued as COSV100540506; called by muse, mutect2, varscan2
- GPR61 | c.1295G>A p.S432N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100879801; called by muse, mutect2, varscan2
- GRIK4 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101483366; called by muse, mutect2, varscan2
- GRIPAP1 | c.643A>T p.S215C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100904138; called by muse, mutect2, varscan2
- GRM4 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1431545411, COSV65210816; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 26/94 reads (28%) | catalogued as rs754199513; called by mutect2, varscan2
- H2BW1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs372943452, COSV54221050; called by muse, mutect2
- HACE1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.746); catalogued as COSV99493168; called by muse, mutect2, varscan2
- HCFC1 | c.2290G>A p.G764S | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100128247; called by muse, mutect2, varscan2
- HDAC2 | c.33del p.V12Sfs*20 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs759078191; called by mutect2, varscan2
- HECTD1 | c.6121del p.I2041Lfs*27 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as rs758518381; called by mutect2, pindel, varscan2
- HELZ | c.4988C>T p.S1663L | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV100698451; called by muse, mutect2, varscan2
- HERC1 | c.7218G>T p.M2406I | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV101496280; called by muse, mutect2, varscan2
- HFE | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745423589, COSV100352486; called by muse, mutect2, varscan2
- HGS | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100230123; called by muse, mutect2, varscan2
- HINFP | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV100640805; called by muse, mutect2, varscan2
- HIVEP2 | c.4957A>G p.N1653D | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99171404; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs761272507; called by mutect2, varscan2
- HOOK1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs368144967; called by muse, mutect2, varscan2
- HS3ST5 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs140386644, COSV57142882; called by muse, mutect2, varscan2
- HTR1A | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV60500357; called by muse, mutect2
- HTT | c.3853G>A p.D1285N | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1312264462, COSV100750257; called by muse, mutect2, varscan2
- ICAM3 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV99348814; called by muse, mutect2, varscan2
- IGHMBP2 | c.1913C>T p.T638M | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs747465472, COSV99661657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 15/26 reads (58%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS1 | c.2603G>A p.R868H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs751375964, COSV101247291; called by muse, mutect2, varscan2
- INTS3 | c.2636G>T p.W879L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99669617, COSV99669686; called by muse, mutect2
- IRF5 | c.469C>A p.L157M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as COSV99977418; called by muse, mutect2, varscan2
- ISYNA1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1449977122, COSV99525907; called by muse, mutect2, varscan2
- ITPR1 | c.6185G>A p.G2062D (on ENST00000354582; = p.G2007D on NM_002222.7) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228959; called by muse, mutect2, varscan2
- ITPR2 | c.7250del p.L2417* | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs1288961144; called by mutect2, pindel, varscan2
- IZUMO1R | c.649C>T p.R217C (on ENST00000440961; = p.R224C on NM_001199206.3) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs373997875; called by muse, mutect2, varscan2
- JAG1 | c.1792G>A p.V598I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.581); catalogued as rs770729371, COSV99652306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JMJD1C | c.4543T>C p.S1515P | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100550052; called by muse, mutect2, varscan2
- KCND1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs1557058590, COSV54413304; called by mutect2, varscan2
- KCNQ2 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV60432240; called by muse, mutect2, varscan2
- KHSRP | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101231118; called by muse, mutect2, varscan2
- KIAA1109 | c.1271T>C p.M424T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52668927, COSV99145361; called by muse, mutect2, varscan2
- KIF1A | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747643976, COSV57487522; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL34 | c.861del p.R288Afs*7 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs762518653; called by mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as COSV52930337; called by mutect2, varscan2
- KMT2A | c.9833C>A p.S3278Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV100627590; called by muse, mutect2, varscan2
- KMT2B | c.1102A>G p.K368E | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99385813; called by muse, mutect2, varscan2
- KRT222 | c.349A>C p.K117Q | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as COSV101229465; called by muse, mutect2, varscan2
- KRT37 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99845211; called by muse, mutect2, varscan2
- KTN1 | c.3319G>A p.A1107T (on ENST00000395314 / NM_001271014.2; = p.A1078T on NM_004986.4) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100618290; called by muse, mutect2, varscan2
- LAMB1 | c.1698+1G>A p.X566_splice | Splice Site (SNP) | VAF 42/96 reads (44%) | catalogued as rs773227979, COSV99739551; called by muse, mutect2, varscan2
- LAMB3 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs146125956, COSV99049406; called by muse, mutect2
- LEMD2 | c.1184T>C p.I395T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV99540355; called by muse, mutect2, varscan2
- LIN7A | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs762931661, COSV99691571; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMNA | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.101); catalogued as COSV100738437; called by muse, mutect2, varscan2
- LONRF3 | c.1816G>A p.A606T (on ENST00000371628 / NM_001031855.3; = p.A565T on NM_024778.5) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100504182; called by muse, mutect2, varscan2
- LPAR4 | c.148T>C p.F50L | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV101425054; called by muse, mutect2, varscan2
- LRFN4 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100540609; called by muse, mutect2
- LRSAM1 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780605033, COSV55938634; called by muse, mutect2
- LRWD1 | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as COSV99479093; called by muse, mutect2, varscan2
- LTBP4 | c.4224dup p.A1409Rfs*3 (on ENST00000308370 / NM_001042544.1; = p.A1372Rfs*3 on NM_003573.2) | Frame Shift Ins (INS) | VAF 20/51 reads (39%) | catalogued as rs754757253; called by mutect2, varscan2
- LY9 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs571520073, COSV99625970; called by muse, mutect2
- LYPLA2 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778054965, COSV99862040; called by muse, mutect2, varscan2
- LZTS1 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV99742526; called by muse, mutect2, varscan2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as rs752869239; called by mutect2, varscan2
- MAOB | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.609); catalogued as COSV65204980; called by muse, mutect2, varscan2
- MAP1A | c.7001C>T p.P2334L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.68); catalogued as rs1395279764, COSV100287879; called by muse, mutect2, varscan2
- MAP2K1 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100198498; called by muse, mutect2, varscan2
- MAPK3 | c.245G>A p.C82Y | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99531125; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs765554926, COSV99167596; called by muse, mutect2, varscan2
- MARK2 | c.2363T>G p.L788R (on ENST00000402010 / NM_001039469.2; = p.L724R on NM_004954.5) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100035984; called by muse, varscan2
- MBD1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs777428957, COSV99495171; called by muse, mutect2, varscan2
- MCF2L2 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100190858, COSV61059537; called by muse, mutect2, varscan2
- MDH1B | c.1382A>C p.K461T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100982105; called by muse, mutect2, varscan2
- ME2 | c.341C>A p.P114Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100360572; called by mutect2, varscan2
- MED12 | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100375378; called by muse, mutect2, varscan2
- MGAT5B | c.2162G>A p.S721N (on ENST00000569840 / NM_001199172.2; = p.S719N on NM_144677.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.116); catalogued as COSV100047043; called by muse, mutect2, varscan2
- MICU2 | c.390G>A p.K130= | Splice Region (SNP) | VAF 20/70 reads (29%) | catalogued as COSV101212387; called by muse, mutect2, varscan2
- MKS1 | c.1587A>G p.L529= | Splice Region (SNP) | VAF 23/48 reads (48%) | catalogued as COSV99836142; called by muse, mutect2, varscan2
- MKS1 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.038); catalogued as rs775391594, COSV58305144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs751465048; called by mutect2, varscan2
- MMP15 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99539184; called by muse, mutect2, varscan2
- MMRN1 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.758); catalogued as rs368641237; called by muse, mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs757379917; called by mutect2, varscan2
- MPDZ | c.1879A>G p.T627A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.978); catalogued as COSV100060270; called by muse, mutect2, varscan2
- MPDZ | c.854T>G p.L285R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100060273, COSV100060768; called by muse, mutect2, varscan2
- MRPS26 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.68); catalogued as COSV99848569; called by muse, mutect2, varscan2
- MRTFB | c.3239C>T p.A1080V (on ENST00000571589 / NM_001365412.2; = p.A1030V on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs759268044, COSV57957690; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs767880823; called by mutect2, varscan2
- MTRES1 | c.663C>A p.Y221* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100261087; called by muse, mutect2, varscan2
- MTSS2 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs757163615, COSV100116151; called by muse, mutect2, varscan2
- MUC17 | c.7730G>T p.R2577I | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV100071103, COSV100074146, COSV60304623; called by muse, mutect2, varscan2
- MUC21 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs761978398, COSV66220765; called by muse, varscan2
- MXI1 | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV99491196; called by muse, mutect2, varscan2
- MYOM2 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); catalogued as COSV100036346; called by muse, mutect2
- MYOM3 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs373823143; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs763929397; called by mutect2, varscan2
- NADSYN1 | c.1687C>G p.L563V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100034346; called by muse, mutect2, varscan2
- NCOR2 | c.3178del p.R1060Vfs*3 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | catalogued as rs749518211, COSV100656528, COSV62300840; called by mutect2, pindel, varscan2
- NDUFS2 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs1332029804, COSV57155253; called by muse, mutect2, varscan2
- NFU1 | c.550A>T p.T184S (on ENST00000410022 / NM_001002755.4; = p.T160S on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.678); catalogued as COSV100360972, COSV100361151; called by muse, mutect2, varscan2
- NKAPD1 | c.479dup p.Q161Afs*26 (on ENST00000280352 / NM_001082970.2; = p.Q162Afs*26 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 15/33 reads (45%) | catalogued as rs902183545; called by mutect2, varscan2
- NKD1 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV99193984; called by muse, mutect2
- NLRP2 | c.2688G>T p.E896D | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV99671729; called by muse, mutect2, varscan2
- NLRP9 | c.1661A>G p.E554G | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100242400; called by muse, mutect2
- NMUR2 | c.889T>C p.W297R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99676507; called by muse, mutect2, varscan2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs753934412; called by mutect2, pindel, varscan2
- NOD1 | c.1523del p.G508Vfs*106 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs1210143813; called by mutect2, pindel, varscan2
- NOP9 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs914754352, COSV99350396; called by muse, mutect2, varscan2
- NOTUM | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as rs776143547, COSV101293744; called by muse, mutect2, varscan2
- NPAP1 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100274580; called by muse, mutect2, varscan2
- NRTN | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs371970077; called by muse, mutect2, varscan2
- NSMF | c.447C>A p.D149E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.993); catalogued as COSV99479853; called by muse, mutect2, varscan2
- NTAN1 | c.890del p.N297Mfs*63 | Frame Shift Del (DEL) | VAF 36/88 reads (41%) | catalogued as rs753931847; called by mutect2, varscan2
- NUBP1 | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99296590; called by mutect2, varscan2
- NUP210L | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.1); catalogued as COSV55149665, COSV99666923; called by muse, mutect2, varscan2
- OBP2A | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); catalogued as rs1385974838, COSV59792958; called by muse, mutect2, varscan2
- OR10J5 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV100604594; called by muse, mutect2, varscan2
- OR2D2 | c.553T>G p.L185V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.779); catalogued as COSV100203688; called by muse, mutect2
- OR2M7 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 57/137 reads (42%) | catalogued as COSV100522383; called by muse, mutect2, varscan2
- OR5L1 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100449862; called by muse, mutect2, varscan2
- OR6N1 | c.907A>G p.R303G | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100625017; called by muse, mutect2, varscan2
- PADI2 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.671); catalogued as rs767108869, COSV100970825; called by muse, mutect2, varscan2
- PAQR6 | c.553C>T p.R185C (on ENST00000292291 / NM_001272108.2; = p.R79C on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773323431, COSV99430646; called by muse, mutect2, varscan2
- PASD1 | c.1340C>A p.P447Q | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100948990; called by muse, mutect2, varscan2
- PBXIP1 | c.1678T>C p.W560R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.341); catalogued as COSV63776869; called by muse, mutect2, varscan2
- PCBP4 | c.1117C>A p.P373T (on ENST00000322099 / NM_033010.2; = p.P330T on NM_020418.4) | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV100436861; called by muse, mutect2, varscan2
- PCDH12 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51525754; called by muse, mutect2, varscan2
- PCDHB13 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV53393295; called by muse, mutect2, varscan2
- PCDHB9 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.591); catalogued as rs782383850, COSV53379247; called by muse, mutect2, varscan2
- PCDHGA12 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs759095332, COSV99337160; called by muse, mutect2, varscan2
- PCDHGB4 | c.2217del p.N740Tfs*26 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs1456939693; called by mutect2, pindel, varscan2
- PCLO | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV100426267; called by muse, mutect2, varscan2
- PDRG1 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99148445; called by muse, mutect2, varscan2
- PDS5A | c.2702A>G p.Q901R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV100337063, COSV57828967; called by muse, mutect2, varscan2
- PEAR1 | c.545A>T p.Y182F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99440405; called by muse, mutect2, varscan2
- PEX5 | c.1769G>A p.R590Q (on ENST00000420616; = p.R582Q on NM_000319.5) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.077); catalogued as rs779049461, COSV99870591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHF3 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs375919837; called by muse, mutect2, varscan2
- PHKG2 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs773982918, COSV100079310; called by muse, mutect2, varscan2
- PIGC | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.413); catalogued as rs774871441, COSV51131840; called by muse, mutect2, varscan2
- PIGG | c.2825G>A p.R942H (on ENST00000453061 / NM_001127178.3; = p.R934H on NM_017733.4) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755336453, COSV56317642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | catalogued as rs749506841; called by mutect2, varscan2
- PLAG1 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV100387659; called by muse, mutect2, varscan2
- PLCB3 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs965422130, COSV99657031; called by muse, mutect2, varscan2
- PLEKHA1 | c.877G>T p.G293C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV100935407; called by muse, mutect2, varscan2
- PLEKHG4B | c.1051C>A p.H351N (on ENST00000283426; = p.H707N on NM_052909.5) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.134); catalogued as COSV99359586; called by muse, mutect2, varscan2
- PNMA5 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as rs1556924555, COSV100721554; called by muse, mutect2, varscan2
- POLRMT | c.3406G>A p.A1136T | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs550982985, COSV52112348; called by muse, mutect2, varscan2
- PON3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV99672219; called by muse, mutect2, varscan2
- POU4F2 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs867084774, COSV55582937; called by muse, mutect2, varscan2
- POU4F2 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as rs759244883, COSV55586370; called by muse, mutect2, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs763475304; called by mutect2, pindel, varscan2
- PPP1R13B | c.1531del p.Q511Sfs*39 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs758922105; called by mutect2, pindel, varscan2
- PPP1R1B | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV99566070; called by muse, mutect2, varscan2
- PPP1R32 | c.502T>C p.F168L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as COSV100087599; called by muse, mutect2, varscan2
- PPP3CC | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99251682; called by muse, mutect2, varscan2
- PRAMEF20 | c.757_759del p.K253del | In Frame Del (DEL) | VAF 70/216 reads (32%) | catalogued as rs1323062110; called by pindel, varscan2
- PRDX6 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs1019938578, COSV100458359; called by muse, mutect2, varscan2
- PRKAR1B | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs765662228, COSV100816490; called by muse, mutect2, varscan2
- PRKDC | c.7528T>A p.L2510M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100037895; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 21/37 reads (57%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR12 | c.784C>T p.R262C (on ENST00000615927; = p.R1083C on NM_020719.3) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1230662136, COSV101330529; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | catalogued as rs781858060; called by mutect2, varscan2
- PRRT2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs754897123, COSV54881782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSMB8 | c.434G>A p.R145H (on ENST00000374882 / NM_148919.4; = p.R141H on NM_004159.5) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs1222974201, COSV100841070; called by muse, mutect2, varscan2
- PTPRD | c.2969A>G p.Y990C | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100642515, COSV61952067; called by muse, mutect2
- PTPRF | c.2368G>T p.E790* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100740425; called by muse, mutect2, varscan2
- PXN | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99935570; called by muse, mutect2, varscan2
- R3HCC1L | c.2078G>A p.R693H (on ENST00000612478 / NM_001256619.2; = p.R679H on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs772754682, COSV100106977; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.178); catalogued as rs369410531; called by muse, mutect2, varscan2
- RAP1GAP | c.955G>A p.V319M | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs536090388, COSV99264544; called by muse, mutect2, varscan2
- RB1 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.431); catalogued as rs373601944, COSV57295692, COSV57306691; ClinVar: uncertain significance / likely benign / not provided; called by muse, mutect2, varscan2
- RBBP6 | c.2522A>T p.Y841F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as COSV100154111; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM4B | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100026336; called by muse, mutect2, varscan2
- RC3H1 | c.2862T>A p.H954Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.4); catalogued as COSV99280886; called by muse, mutect2, varscan2
- RDH13 | c.450C>A p.H150Q (on ENST00000415061 / NM_001145971.2; = p.H79Q on NM_138412.4) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99401325; called by muse, mutect2, varscan2
- RFC4 | c.890T>A p.I297K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99960913; called by muse, mutect2, varscan2
- RFPL3 | c.124G>A p.V42I (on ENST00000249007 / NM_001098535.1; = p.V13I on NM_006604.2) | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.069); catalogued as rs770073454, COSV50748548; called by muse, mutect2, varscan2
- RGS11 | c.1166T>C p.L389P (on ENST00000397770 / NM_183337.3; = p.L368P on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99395558; called by muse, mutect2, varscan2
- RHBDF1 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs1471400416, COSV51953521; called by muse, mutect2, varscan2
- RHBDL1 | c.593T>C p.V198A (on ENST00000219551 / NM_001318733.2; = p.V133A on NM_001278720.2) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as COSV99555293; called by muse, mutect2
- RHPN1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs780121829, COSV100000325; called by muse, mutect2, varscan2
- RNF123 | c.2687C>T p.T896I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.991); catalogued as rs1258560145, COSV100246384; called by muse, mutect2, varscan2
- RNF17 | c.3142G>A p.D1048N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99691847; called by muse, mutect2, varscan2
- RNF214 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as rs545939645, COSV56121769; called by muse, mutect2, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPUSD4 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs765735907, COSV100028563; called by muse, mutect2, varscan2
- RXRA | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384649916, COSV62683671; called by muse, mutect2, varscan2
- SAXO1 | c.896A>T p.D299V | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV101000032; called by muse, mutect2, varscan2
- SCN1A | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs398123601, COSV100318826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK2 | c.6398G>T p.R2133L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as rs201326991, COSV101166581; called by muse, mutect2, varscan2
- SELENBP1 | c.457G>T p.G153* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV100923556; called by muse, mutect2, varscan2
- SERBP1 | c.1099C>T p.R367C (on ENST00000370995 / NM_001018067.2; = p.R346C on NM_015640.4) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63413758; called by muse, mutect2, varscan2
- SERINC3 | c.141_143del p.L48del | In Frame Del (DEL) | VAF 28/70 reads (40%) | catalogued as rs1429279292; called by pindel, varscan2
- SHANK2 | c.3220G>A p.V1074I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.379); catalogued as rs782391344, COSV99571533; called by muse, mutect2, varscan2
- SHPRH | c.1501G>C p.G501R | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99261032; called by muse, mutect2, varscan2
- SIRT1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1426968560, COSV53019448; called by muse, mutect2, varscan2
- SIX3 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as CM064273, COSV99577999; called by muse, mutect2, varscan2
- SKAP1 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745681170, COSV100411227; called by muse, mutect2, varscan2
- SLC17A1 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99765488; called by muse, mutect2, varscan2
- SLC25A47 | c.211T>C p.F71L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV100836428; called by muse, mutect2, varscan2
- SLC2A11 | c.98C>A p.S33Y (on ENST00000345044 / NM_001024938.4; = p.S40Y on NM_030807.5) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763508970, COSV99740987; called by muse, mutect2, varscan2
- SLC30A9 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 45/94 reads (48%) | catalogued as COSV100047874, COSV52554475; called by muse, mutect2, varscan2
- SLC36A4 | c.179+1G>A p.X60_splice | Splice Site (SNP) | VAF 19/37 reads (51%) | catalogued as rs759794346, COSV58395726; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC4A3 | c.2652del p.S885Afs*22 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | catalogued as rs760972612; called by mutect2, pindel, varscan2
- SLC5A10 | c.1112C>T p.A371V (on ENST00000395645 / NM_001042450.4; = p.A387V on NM_152351.5) | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs199555158, COSV100524692; called by muse, mutect2, varscan2
- SLC5A3 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100757716; called by muse, mutect2, varscan2
- SLC66A2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.193); catalogued as COSV100301585; called by muse, mutect2, varscan2
- SLC6A6 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100691787; called by muse, mutect2, varscan2
- SLC7A3 | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV99979246; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
- SLITRK3 | c.2627del p.G876Efs*10 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | catalogued as COSV53845814, COSV99578942, COSV99580309; called by mutect2, pindel, varscan2
- SLITRK3 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99578179; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCA2 | c.3801C>G p.N1267K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs763135326, COSV100570110; called by muse, mutect2, varscan2
- SMOX | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99602732; called by muse, mutect2, varscan2
- SND1 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100689460; called by muse, mutect2, varscan2
- SNX17 | c.1385T>A p.F462Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99277144; called by muse, mutect2, varscan2
- SORBS2 | c.3130del p.E1044Nfs*65 (on ENST00000284776 / NM_021069.5; = p.E610Nfs*65 on NM_003603.6) | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs772549791, COSV52996321; called by mutect2, pindel, varscan2
- SORCS2 | c.3463A>G p.S1155G | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV100211095; called by muse, mutect2, varscan2
- SOS2 | c.3664C>T p.R1222W | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1232489201, COSV53572939; called by muse, mutect2, varscan2
- SOX15 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100001917; called by muse, mutect2, varscan2
- SP6 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs964114239, COSV100646920; called by muse, mutect2, varscan2
- SPRY3 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100249098; called by muse, mutect2, varscan2
- SPTA1 | c.3417G>T p.K1139N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV100934037; called by muse, mutect2, varscan2
- SPTBN5 | c.8366C>A p.A2789D | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100310393; called by muse, mutect2, varscan2
- SRSF6 | c.384T>A p.D128E | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99719592; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs752994755; called by mutect2, varscan2
- STARD8 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV99365998; called by muse, mutect2, varscan2
- STC2 | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs757329205, COSV99438054; called by muse, mutect2, varscan2
- STK40 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100828466; called by muse, mutect2, varscan2
- SUGP1 | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55921900; called by muse, mutect2, varscan2
- SULF1 | c.743G>C p.S248T | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV99481734; called by muse, varscan2
- SUPT3H | c.950C>A p.A317D (on ENST00000371460 / NM_181356.3; = p.A306D on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100175874; called by muse, mutect2, varscan2
- SYMPK | c.2894C>T p.A965V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99679478; called by muse, mutect2, varscan2
- TACC2 | c.8842A>G p.S2948G (on ENST00000334433; = p.S1026G on NM_006997.4) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1360412716, COSV99586399; called by muse, mutect2, varscan2
- TASOR2 | c.5861G>A p.C1954Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs751826299, COSV100049845; called by muse, mutect2, varscan2
- TBP | c.823C>A p.L275I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100027103; called by muse, mutect2, varscan2
- TCF19 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99462604; called by muse, mutect2, varscan2
- TCTE1 | c.415T>C p.W139R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV101025260; called by muse, mutect2, varscan2
- TDGF1 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs369887696, COSV99947605; called by muse, mutect2, varscan2
- TEP1 | c.7543C>A p.Q2515K | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99401382; called by muse, mutect2, varscan2
- TERF1 | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52577756, COSV99400781; called by muse, mutect2, varscan2
- TERF2IP | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs367571165; called by muse, mutect2, varscan2
- TESK1 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs757382571, COSV99427223; called by muse, varscan2
- TFAM | c.441del p.E148Sfs*2 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs544132101; called by mutect2, varscan2
- TIAL1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as COSV100958315; called by muse, mutect2, varscan2
- TJP1 | c.3186G>C p.E1062D | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100632144; called by muse, mutect2, varscan2
- TJP3 | c.1510G>A p.V504M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs779807105, COSV99515630; called by muse, mutect2, varscan2
- TLK1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs776521445, COSV100687133; called by muse, mutect2, varscan2
- TLL2 | c.2359C>A p.L787M | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV100780072; called by muse, mutect2, varscan2
- TLN2 | c.5416G>A p.E1806K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV100167724; called by muse, mutect2, varscan2
- TLR8 | c.1319G>T p.S440I (on ENST00000218032 / NM_138636.5; = p.S458I on NM_016610.4) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV99486717; called by muse, mutect2, varscan2
- TM2D1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV53906878; called by muse, mutect2, varscan2
- TMEFF1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs1288519569, COSV100614293; called by muse, mutect2, varscan2
- TMEM86A | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs372889645, COSV55011715; called by muse, mutect2, varscan2
- TNK2 | c.2365T>G p.S789A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100360847; called by muse, mutect2, varscan2
- TNS1 | c.3905G>A p.R1302H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs533811485, COSV50765331; called by muse, mutect2, varscan2
- TNXB | c.12199C>T p.R4067C (on ENST00000647633; = p.R3820C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs138558351, COSV100925672, COSV64474468; called by muse, mutect2, varscan2
- TRMT2A | c.1363_1364del p.K455Efs*23 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs772630386; called by mutect2, pindel, varscan2
- TRNAU1AP | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as COSV100867804; called by muse, mutect2, varscan2
- TRPC7 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV61462523; called by muse, mutect2, varscan2
- TTC19 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs139693104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC3 | c.4718T>C p.L1573P | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100694890; called by muse, mutect2, varscan2
- TTK | c.796A>G p.K266E | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.22); catalogued as rs1216481378, COSV100035855; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.91386T>C p.Y30462= (on ENST00000591111; = p.Y23038= on NM_003319.4) | Splice Region (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100589318; called by muse, mutect2, varscan2
- TUBA3C | c.1080del p.T361Rfs*18 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs750889205; called by mutect2, pindel
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs760251146; called by mutect2, varscan2
- TXNRD1 | c.1940G>A p.C647Y (on ENST00000525566 / NM_001093771.3; = p.C549Y on NM_003330.4) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61599340; called by muse, mutect2, varscan2
- UBE2I | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100330379; called by muse, mutect2, varscan2
- UBE2R2 | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99601863; called by muse, mutect2, varscan2
- UGDH | c.1294del p.M432Cfs*2 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs774133578; called by mutect2, pindel, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 36/46 reads (78%) | catalogued as rs767420916; called by mutect2, varscan2
- USF3 | c.3746G>A p.S1249N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1406919890, COSV100324606; called by muse, mutect2, varscan2
- USP35 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.94); catalogued as rs780745175, COSV60866600; called by muse, mutect2, varscan2
- USP40 | c.3441del p.K1147Nfs*12 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs572063854; called by mutect2, varscan2
- USP47 | c.1108_1110del p.K370del (on ENST00000399455 / NM_001372095.1; = p.K282del on NM_017944.4 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 28/50 reads (56%) | catalogued as rs1299361681; called by pindel, varscan2
- USP6NL | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99509148; called by muse, mutect2
- UTS2R | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV57452299; called by muse, mutect2, varscan2
- UVSSA | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs200196963; called by muse, mutect2, varscan2
- VANGL1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765459331, COSV59619287; called by muse, mutect2, varscan2
- VANGL2 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs758501785, COSV63604509; called by muse, mutect2, varscan2
- VPS13A | c.4982T>C p.M1661T | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100651912; called by muse, mutect2, varscan2
- VPS50 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.854); catalogued as rs754664638, COSV52495236; called by muse, mutect2, varscan2
- WASHC2C | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV100313738; called by muse, mutect2, varscan2
- WDR91 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as rs761395879, COSV100615506; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 28/43 reads (65%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WHAMM | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs367857647, COSV54497961; called by muse, mutect2, varscan2
- XIRP2 | c.1537dup p.D513Gfs*10 (on ENST00000628543; = p.D688Gfs*10 on NM_152381.6) | Frame Shift Ins (INS) | VAF 13/28 reads (46%) | catalogued as rs745648385; called by mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBTB22 | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99801256; called by muse, mutect2, varscan2
- ZBTB48 | c.1853T>C p.I618T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV100887174; called by muse, mutect2, varscan2
- ZDHHC12 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99403193; called by muse, mutect2, varscan2
- ZDHHC7 | c.831del p.S280Hfs*5 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as COSV58214455; called by mutect2, pindel, varscan2
- ZDHHC8 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100272466; called by muse, mutect2, varscan2
- ZDHHC8 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 37/77 reads (48%) | catalogued as COSV100272470; called by muse, mutect2, varscan2
- ZFHX4 | c.6756del p.D2253Mfs*4 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as COSV99261162; called by mutect2, pindel, varscan2
- ZFYVE9 | c.2129C>G p.A710G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99819183; called by muse, mutect2, varscan2
- ZMYM6 | c.3893del p.N1298Ifs*9 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | catalogued as COSV100593369; called by mutect2, pindel, varscan2
- ZNF175 | c.2017T>C p.C673R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99219217; called by muse, mutect2, varscan2
- ZNF217 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV100184095; called by muse, mutect2, varscan2
- ZNF335 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs147156367, COSV100532531; called by muse, mutect2, varscan2
- ZNF438 | c.2438C>T p.T813M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as rs773162962, COSV100061032; called by muse, mutect2, varscan2
- ZNF496 | c.390+1G>A p.X130_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99665062; called by muse, varscan2
- ZNF517 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs770935296, COSV100743350; called by muse, mutect2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 12/16 reads (75%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 42/134 reads (31%) | catalogued as rs782441698; called by mutect2, pindel, varscan2
- ZNF644 | c.871del p.R291Efs*7 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs749473342; called by mutect2, varscan2
- ZNF701 | c.986G>A p.C329Y (on ENST00000301093; = p.C263Y on NM_018260.3) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV99990533; called by muse, mutect2, varscan2
- ZNF770 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV100695773; called by muse, mutect2, varscan2
- ZP2 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as rs763479712, COSV54817441; called by muse, mutect2, varscan2
- ZSWIM5 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1319849843, COSV100655235, COSV62732292; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3464del p.G1155Efs*42 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.125_149delinsCACCGACGCCACGGCCTTCTGGT p.G42Afs*97 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by pindel, varscan2*
- AMD1 | c.404_405del p.E135Vfs*3 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by pindel, varscan2
- ARHGAP33 | c.2150del p.P717Lfs*79 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- BCAR3 | c.481del p.R161Dfs*15 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | called by mutect2, varscan2
- BEND4 | c.1226_1229del p.K409Mfs*49 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by pindel, varscan2
- BICRAL | c.1343_1344del p.S448Ffs*16 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- BRF1 | c.876del p.S293Rfs*11 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- BRPF3 | c.2561dup p.E855Gfs*9 | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | called by mutect2, varscan2
- C3P1 | n.2765G>T | Splice Region (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- CALHM5 | c.117del p.F39Lfs*10 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- CFAP20 | c.83dup p.V29Gfs*11 | Frame Shift Ins (INS) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- COL25A1 | c.37del p.R13Gfs*42 | Frame Shift Del (DEL) | VAF 37/109 reads (34%) | called by mutect2, pindel, varscan2
- CREB3L1 | c.1371del p.P458Rfs*25 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- DDX3X | c.1352del p.K451Rfs*44 (on ENST00000399959; = p.K452Rfs*44 on NM_001356.5) | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | called by mutect2, varscan2
- DERL3 | c.665dup p.E223* | Frame Shift Ins (INS) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- ESCO1 | c.318del p.K106Nfs*2 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- EYA3 | c.1342_1347del p.L448_R449del | In Frame Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- FBL | c.951del p.K318Rfs*2 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | called by mutect2, pindel, varscan2
- FBXO10 | c.1640del p.N547Tfs*22 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- FBXW4 | c.1609dup p.L537Pfs*113 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- FRG2 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRMD4A | c.1693del p.L565Yfs*52 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | called by mutect2, pindel, varscan2
- GCLM | c.148del p.T50Pfs*2 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | called by mutect2, varscan2
- GOLGB1 | c.6215del p.K2072Rfs*6 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- GPC4 | c.217_219del p.E73del | In Frame Del (DEL) | VAF 24/70 reads (34%) | called by pindel, varscan2
- GRM8 | c.888dup p.L297Tfs*14 | Frame Shift Ins (INS) | VAF 35/93 reads (38%) | called by mutect2, varscan2
- H1-4 | c.116dup p.V40Gfs*7 | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- HAUS5 | c.1258del p.E420Rfs*3 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- HECW2 | c.4175del p.G1392Vfs*19 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- HSPA8 | c.459_460del p.Q154Afs*17 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by pindel, varscan2
- INO80D | c.1130_1133del p.Y377Ffs*43 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | called by pindel, varscan2
- ITPR2 | c.5509del p.R1837Gfs*7 | Frame Shift Del (DEL) | VAF 48/169 reads (28%) | called by mutect2, pindel, varscan2
- JMJD1C | c.7110_7112del p.E2370del | In Frame Del (DEL) | VAF 14/52 reads (27%) | called by pindel, varscan2
- KMT2B | c.939del p.V314* | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- KMT2B | c.3145dup p.A1049Gfs*39 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- KRT80 | c.111del p.P39Rfs*20 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by pindel, varscan2
- LDB3 | c.1401del p.N468Tfs*24 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- LRP1B | c.11869dup p.R3957Kfs*11 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- MAP2K3 | c.862del p.Q288Sfs*19 (on ENST00000342679 / NM_145109.3; = p.Q259Sfs*19 on NM_002756.4) | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | called by mutect2, pindel, varscan2
- MAP9 | c.1592del p.N531Ifs*27 | Frame Shift Del (DEL) | VAF 28/73 reads (38%) | called by mutect2, pindel, varscan2
- MEF2A | c.945del p.T316Qfs*25 (on ENST00000557942 / NM_001319206.2; = p.T310Qfs*25 on NM_005587.4 and 8 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | called by mutect2, pindel, varscan2
- MEF2B | c.16del p.I6Sfs*14 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- MFSD1 | c.1033del p.H345Tfs*2 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | called by mutect2, pindel, varscan2
- MLEC | c.741del p.K247Nfs*50 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- MMP13 | c.1108del p.I370Yfs*13 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- MTSS2 | c.1677del p.G560Afs*34 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- NFASC | c.3445dup p.L1149Pfs*4 (on ENST00000339876 / NM_001378329.1; = p.L1078Pfs*4 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 34/103 reads (33%) | called by mutect2, pindel, varscan2
- NINL | c.4131del p.A1378Qfs*22 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- NLGN2 | c.474del p.K158Nfs*22 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | called by mutect2, varscan2
- NOP58 | c.1571del p.K524Rfs*22 | Frame Shift Del (DEL) | VAF 28/62 reads (45%) | called by mutect2, varscan2
- NRAP | c.2255del p.K752Rfs*54 (on ENST00000359988 / NM_001322945.2; = p.K717Rfs*54 on NM_006175.4) | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | called by mutect2, pindel, varscan2
- PCDHA12 | c.558del p.D187Ifs*8 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- PLEKHM1 | c.1944del p.E649Rfs*62 | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.5551_5552del p.S1851Rfs*21 | Frame Shift Del (DEL) | VAF 44/106 reads (42%) | called by pindel, varscan2
- PSMD4 | c.174_175del p.C58* | Frame Shift Del (DEL) | VAF 35/110 reads (32%) | called by pindel, varscan2
- PTEN | c.79+3_79+14del | Splice Region (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- RAB6D | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAI1 | c.367del p.A123Pfs*23 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- REV1 | c.1174dup p.M392Nfs*12 | Frame Shift Ins (INS) | VAF 10/25 reads (40%) | called by mutect2, varscan2
- RFX2 | c.423del p.S142Afs*72 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | called by mutect2, pindel, varscan2
- RNF207 | c.814_816del p.K272del | In Frame Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- RYR3 | c.5609del p.P1870Hfs*87 | Frame Shift Del (DEL) | VAF 22/45 reads (49%) | called by mutect2, pindel, varscan2
- SALL3 | c.1953del p.L652Cfs*2 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- SH2B1 | c.659del p.P220Lfs*12 | Frame Shift Del (DEL) | VAF 53/149 reads (36%) | called by mutect2, pindel, varscan2
- SLC12A4 | c.3120_3122del p.L1041del | In Frame Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 22/47 reads (47%) | called by mutect2, varscan2
- SPIRE1 | c.1971del p.K657Nfs*36 (on ENST00000409402 / NM_001128626.2; = p.K643Nfs*36 on NM_020148.3) | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- STT3B | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- TAF6 | c.1779del p.S594Afs*111 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- TFAP2C | c.241del p.E81Kfs*56 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- TNPO3 | c.2541del p.Y848Ifs*25 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- TNRC6A | c.2409del p.W804Gfs*99 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- TPRN | c.1805_1807del p.E602del | In Frame Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- TUT4 | c.550del p.I184Ffs*11 | Frame Shift Del (DEL) | VAF 28/56 reads (50%) | called by mutect2, varscan2
- USP21 | c.1426del p.S476Vfs*3 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- USP47 | c.3360del p.G1121Efs*22 (on ENST00000399455 / NM_001372095.1; = p.G1033Efs*22 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- VPS13A | c.1174del p.T392Pfs*7 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- VPS13C | c.3197del p.N1066Ifs*25 (on ENST00000644861 / NM_020821.3; = p.N1023Ifs*25 on NM_017684.5) | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- VTN | c.721del p.R241Efs*67 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- WASHC2A | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDR62 | c.2331del p.R778Gfs*15 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- XKR4 | c.1499del p.L500* | Frame Shift Del (DEL) | VAF 24/83 reads (29%) | called by mutect2, pindel, varscan2
- ZBTB11 | c.1812del p.K604Nfs*68 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | called by mutect2, varscan2
- ZBTB24 | c.1336_1337del p.K446Efs*27 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- ZBTB39 | c.2066del p.P689Lfs*42 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | called by mutect2, pindel, varscan2
- ZNF275 | c.480del p.S161Vfs*36 | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | called by mutect2, pindel, varscan2
- ZNF407 | c.5837del p.G1946Afs*18 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- ACOT7 | c.1059C>T p.D353= (on ENST00000377855 / NM_181864.3; = p.D343= on NM_007274.4) | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs145849239; called by muse, mutect2, varscan2
- ADGRA1 | c.486C>T p.D162= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs775711151, COSV66926953; called by muse, mutect2, varscan2
- AGAP2 | c.723C>T p.A241= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs1203404967, COSV99221947; called by muse, mutect2
- ALDH1L1 | c.1110C>T p.G370= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV56414202; called by muse, mutect2, varscan2
- ANGEL2 | c.915C>T p.C305= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as rs779665981, COSV64737187; called by muse, mutect2, varscan2
- ANKHD1 | c.2184T>C p.P728= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99781737, COSV99784022; called by muse, mutect2, varscan2
- ANOS1 | c.1614C>T p.G538= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs1487125805, COSV99390278; called by muse, mutect2, varscan2
- ARAP3 | c.2391C>T p.P797= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs773037629, COSV53351584, COSV99499196; called by muse, mutect2, varscan2
- ARHGAP6 | c.1548C>T p.C516= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs765786974, COSV57291516; called by muse, mutect2, varscan2
- ARIH2 | c.207T>C p.S69= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100711144; called by muse, mutect2, varscan2
- ARMCX2 | c.957A>T p.A319= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV100167986; called by muse, mutect2, varscan2
- B4GALNT4 | c.1269C>T p.R423= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs966485552, COSV100327126; called by muse, mutect2, varscan2
- C11orf68 | c.564G>A p.A188= (on ENST00000530188; = p.A229= on NM_031450.4) | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs762790127, COSV100437013; called by muse, mutect2, varscan2
- CAPN13 | c.855C>T p.R285= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99699575; called by muse, mutect2, varscan2
- CELSR2 | c.1617C>T p.R539= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs1208819388, COSV99602809; called by muse, mutect2, varscan2
- CEP135 | c.528G>A p.P176= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs777232769, COSV99954002; called by muse, mutect2, varscan2
- CEP72 | c.426C>T p.S142= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs375775432; called by muse, mutect2, varscan2
- CHRND | c.1470G>A p.L490= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99285446; called by muse, mutect2, varscan2
- CHST15 | c.1683G>A p.T561= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs778681453, COSV100654855; called by muse, mutect2, varscan2
- COL5A1 | c.2181C>T p.G727= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs201298716, COSV65667559; called by muse, mutect2, varscan2
- CPT1B | c.51C>T p.D17= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs199821148, COSV100376435; called by muse, mutect2, varscan2
- CRIM1 | c.1446C>T p.C482= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs755343317, COSV54864366; called by muse, mutect2, varscan2
- CSNK1G2 | c.393C>T p.D131= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs933735468, COSV99729480; called by muse, mutect2, varscan2
- CYB561 | c.495T>A p.A165= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100669055; called by muse, mutect2, varscan2
- DDR2 | c.2031C>T p.S677= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs773962213, COSV63370216; called by muse, mutect2, varscan2
- DDX11 | c.2088C>T p.C696= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs779746853, COSV52502219; called by muse, mutect2, varscan2
- DNAH9 | c.5190A>G p.E1730= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV99303143; called by muse, mutect2, varscan2
- DNM2 | c.2106G>A p.S702= (on ENST00000355667 / NM_001005360.3; = p.S698= on NM_004945.3) | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs554971107, COSV99283987; called by muse, mutect2, varscan2
- DTX1 | c.1311C>A p.L437= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV55658410, COSV99921339; called by muse, mutect2, varscan2
- EEF2KMT | c.441A>G p.E147= | Silent (SNP) | VAF 70/179 reads (39%) | catalogued as rs1368504771, COSV101435292; called by muse, mutect2, varscan2
- EMSY | c.1908G>T p.T636= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs767597942, COSV100595234, COSV58263225; called by muse, mutect2, varscan2
- ENAM | c.3015C>T p.N1005= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV101252853; called by muse, mutect2, varscan2
- ENTPD2 | c.693G>A p.Q231= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100445556; called by muse, mutect2, varscan2
- EP400 | c.1479A>G p.V493= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100200081; called by muse, mutect2, varscan2
- ERBB3 | c.1461T>C p.N487= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99915417; called by muse, mutect2, varscan2
- ERI3 | c.507C>A p.P169= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as COSV100952027; called by muse, mutect2, varscan2
- ESR1 | c.1677C>T p.S559= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs780952321, COSV52788550, COSV52798125; called by muse, mutect2, varscan2
- EXOSC9 | c.987T>C p.P329= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99696656; called by muse, mutect2, varscan2
- FAM151B | c.396C>T p.A132= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs137973083; called by muse, mutect2, varscan2
- FBN1 | c.6387C>T p.D2129= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs147342485, COSV57310318; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOXD2 | c.480C>T p.R160= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV100599138, COSV58303786; called by muse, mutect2, varscan2
- FOXO4 | c.846G>A p.A282= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs1449817786, COSV58576102, COSV58576511; called by muse, mutect2, varscan2
- FOXP2 | c.522A>G p.Q174= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs368614280; ClinVar: benign; called by mutect2, varscan2
- GCN1 | c.1983C>A p.T661= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100324484; called by muse, mutect2, varscan2
- GFPT2 | c.1398C>T p.N466= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1335278161, COSV99517153; called by muse, mutect2, varscan2
- GPR174 | c.990T>C p.P330= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV99337894; called by muse, mutect2, varscan2
- GPR25 | c.637C>T p.L213= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV58497736; called by muse, mutect2, varscan2
- GRIN1 | c.198G>A p.T66= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100159683; called by muse, mutect2, varscan2
- GRIN2A | c.75G>A p.A25= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV58048872; called by muse, mutect2, varscan2
- GRIN3A | c.2742C>T p.G914= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100701313; called by muse, mutect2, varscan2
- HDAC7 | c.2658C>A p.A886= (on ENST00000427332; = p.A925= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99315350; called by muse, mutect2, varscan2
- HECTD4 | c.10560G>T p.P3520= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV101106438; called by muse, mutect2, varscan2
- HNRNPM | c.2103G>A p.S701= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs115721524, COSV55315692; called by muse, mutect2, varscan2
- HS1BP3 | c.847C>T p.L283= | Silent (SNP) | VAF 80/177 reads (45%) | catalogued as COSV100397715; called by muse, mutect2, varscan2
- HSPA13 | c.1062T>C p.S354= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs1264508825, COSV99579800; called by muse, mutect2, varscan2
- IGKV1D-8 | c.205C>T p.L69= | Silent (SNP) | VAF 70/173 reads (40%) | called by muse, mutect2, varscan2
- ITPR1 | c.3573G>A p.E1191= (on ENST00000354582; = p.E1176= on NM_002222.7) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100228953; called by muse, mutect2
- ITPR3 | c.3279G>A p.K1093= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100966783, COSV65411601; called by muse, mutect2, varscan2
- KCNQ5 | c.1911A>G p.S637= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100570822; called by muse, mutect2
- KIF4B | c.1452G>A p.T484= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs1426539253, COSV101469145; called by muse, mutect2, varscan2
- KMT2D | c.3618C>T p.N1206= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs200624640, COSV99976568; ClinVar: benign; called by muse, mutect2, varscan2
- KMT5C | c.63C>T p.L21= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs751392739, COSV99726016; called by muse, mutect2, varscan2
- KRBA1 | c.1977G>A p.E659= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs766448343, COSV99752070; called by muse, mutect2, varscan2
- KRT71 | c.633C>T p.D211= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs113716134; called by muse, mutect2, varscan2
- KRTAP13-4 | c.72C>A p.S24= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs1398158094, COSV100481693; called by muse, mutect2, varscan2
- KRTAP8-1 | c.66G>A p.P22= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs770707950, COSV100297770; called by muse, mutect2, varscan2
- KYNU | c.1335T>C p.H445= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99932633; called by muse, mutect2, varscan2
- LAMB3 | c.2199C>T p.S733= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs748747266, COSV61915038; called by muse, mutect2, varscan2
- LMTK3 | c.2793C>T p.N931= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs1289873090, COSV54315209; called by muse, mutect2, varscan2
- LPCAT1 | c.1110G>A p.A370= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs756860780, COSV99358646; called by muse, mutect2, varscan2
- LRP11 | c.795G>A p.K265= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99497672; called by muse, mutect2
- LTBP4 | c.378G>C p.R126= (on ENST00000308370 / NM_001042544.1; = p.R89= on NM_003573.2) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99180296; called by muse, mutect2, varscan2
- MAGEE1 | c.1470T>C p.P490= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs1386879861, COSV100819215; called by muse, mutect2, varscan2
- MARCO | c.1035A>C p.T345= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100503075; called by muse, mutect2, varscan2
- MIPEP | c.1137G>A p.P379= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs183255758; called by muse, mutect2, varscan2
- MMRN2 | c.948C>T p.H316= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs766994960, COSV100922455; called by muse, mutect2, varscan2
- MNX1 | c.699G>A p.A233= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs1436265640, COSV99429512; called by muse, mutect2, varscan2
- MROH1 | c.4581T>C p.C1527= | Silent (SNP) | VAF 76/133 reads (57%) | called by muse, mutect2, varscan2
- MS4A2 | c.588T>C p.A196= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99626947; called by muse, mutect2, varscan2
- MUC20 | c.1548G>A p.T516= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs560563342, COSV100290798, COSV100291041; called by mutect2, varscan2
- NCAPD3 | c.2970C>T p.S990= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs755582953, COSV101598324; called by muse, mutect2, varscan2
- NCOA2 | c.1860C>T p.A620= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as rs779568773, COSV101475893; called by muse, mutect2, varscan2
- NEPRO | c.570C>A p.V190= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100074850; called by muse, mutect2, varscan2
- NOL7 | c.399G>A p.S133= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs766441029, COSV50581878; called by mutect2, varscan2
- NPC1L1 | c.2571C>T p.F857= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs140093298, COSV99202551; called by muse, mutect2, varscan2
- NUP210L | c.2658G>A p.L886= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs1014436662, COSV99666922; called by muse, mutect2, varscan2
- OR2T5 | c.93T>A p.L31= | Silent (SNP) | VAF 60/166 reads (36%) | catalogued as COSV100822159; called by muse, mutect2, varscan2
- OVGP1 | c.585C>A p.S195= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs1245523776, COSV100867923; called by muse, mutect2, varscan2
- PAQR7 | c.630C>T p.S210= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1030256980, COSV65351911; called by muse, mutect2, varscan2
- PCSK6 | c.861C>T p.V287= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs745919323, COSV59338089; called by muse, mutect2, varscan2
- PDXDC1 | c.1374G>A p.R458= | Silent (SNP) | VAF 38/172 reads (22%) | catalogued as COSV100362825; called by muse, mutect2, varscan2
- PES1 | c.1692G>A p.K564= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV100072925; called by muse, mutect2, varscan2
- PITX3 | c.72G>A p.P24= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs961490778, COSV100892715; called by muse, mutect2, varscan2
- PLEKHA6 | c.147A>G p.S49= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV99691352; called by muse, mutect2
- PLEKHA7 | c.3258C>A p.A1086= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100261776; called by muse, mutect2, varscan2
- PLXNB2 | c.5394G>A p.T1798= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs563052435, COSV63780802; called by muse, mutect2, varscan2
- PNLIPRP2 | c.31C>T p.L11= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100077512; called by muse, mutect2, varscan2
- PPP1R9A | c.894G>A p.Q298= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99194489; called by muse, mutect2, varscan2
- PPP2R2B | c.855G>A p.S285= (on ENST00000394409; = p.S351= on NM_181674.2) | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs772927479, COSV60753716; called by muse, mutect2, varscan2
- PPP2R2C | c.999C>T p.Y333= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs747462237, COSV59445832; called by muse, mutect2, varscan2
- PRDM15 | c.3543G>A p.S1181= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs751836847, COSV54149890; called by muse, mutect2, varscan2
- QSOX1 | c.1341C>T p.F447= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs142755170; called by muse, mutect2, varscan2
- RAVER1 | c.924C>T p.A308= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs549693594, COSV53345497; called by muse, mutect2, varscan2
- RBM19 | c.2878C>T p.L960= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as COSV99925370; called by muse, mutect2, varscan2
- RELCH | c.1542C>T p.D514= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs761037180, COSV99901213; called by muse, mutect2, varscan2
- RELN | c.3411C>T p.G1137= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs137974322; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RIT2 | c.486C>A p.T162= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1170217010, COSV100449498; called by muse, mutect2, varscan2
- RRP1B | c.1920C>T p.S640= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs564010625, COSV100512808; called by muse, mutect2, varscan2
- RUNX1T1 | c.1380G>A p.A460= (on ENST00000265814 / NM_001198628.1; = p.A433= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs146810742; called by muse, mutect2, varscan2
- SBF1 | c.2067T>C p.D689= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1282065085, COSV62369779; called by muse, mutect2
- SEMA3E | c.708T>C p.N236= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs1399787086, COSV100316861; called by muse, mutect2, varscan2
- SH3BP2 | c.333G>A p.S111= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs554077647, COSV100696841; called by muse, mutect2, varscan2
- SIRT6 | c.342C>T p.N114= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs201561008, COSV100511108; called by muse, mutect2, varscan2
- SLC13A3 | c.843C>T p.F281= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs759206007, COSV51712845, COSV51724528; called by muse, mutect2, varscan2
- SLC16A3 | c.555C>T p.G185= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV101125875; called by muse, mutect2, varscan2
- SLC18A1 | c.135G>A p.V45= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99368148; called by muse, mutect2
- SLC25A6 | c.141C>A p.A47= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV101195392; called by muse, mutect2, varscan2
- SLC39A2 | c.414C>T p.D138= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as rs142794092, COSV53869820; called by muse, mutect2, varscan2
- SLC45A3 | c.1434C>T p.T478= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs547421942, COSV65655319, COSV65655872; called by muse, mutect2, varscan2
- SLC5A2 | c.879C>T p.S293= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100392929; called by muse, mutect2, varscan2
- SLC8A2 | c.1975C>T p.L659= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99369510; called by muse, mutect2, varscan2
- SMARCA2 | c.4428C>T p.H1476= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100190022; called by muse, mutect2, varscan2
- SNCG | c.201C>T p.S67= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV62318268; called by muse, mutect2
- SNRNP40 | c.789T>C p.D263= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99744958; called by muse, mutect2, varscan2
- SOX2 | c.354G>A p.T118= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV57621739; called by muse, mutect2, varscan2
- SPTB | c.1572C>T p.L524= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs149192360; called by muse, mutect2, varscan2
- SPTBN1 | c.432G>A p.R144= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV100441469; called by muse, mutect2, varscan2
- SSC4D | c.1383G>A p.T461= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1451319129, COSV99299735; called by muse, mutect2, varscan2
- SSRP1 | c.1956C>A p.S652= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV53478309, COSV99554646; called by muse, mutect2, varscan2
- SYTL1 | c.444G>A p.R148= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100538984; called by muse, mutect2, varscan2
- TET3 | c.822C>T p.C274= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs1158801762, COSV59881919; called by muse, mutect2, varscan2
- THAP12 | c.468C>A p.T156= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs1473027008, COSV99472708; called by muse, mutect2, varscan2
- TIGD4 | c.108C>T p.G36= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100427845; called by muse, mutect2, varscan2
- TMF1 | c.231T>C p.S77= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV101275386; called by muse, mutect2, varscan2
- TNFRSF14 | c.465C>T p.T155= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs149259508; called by muse, mutect2, varscan2
- TP53BP2 | c.855G>A p.E285= (on ENST00000343537 / NM_001031685.3; = p.E156= on NM_005426.2) | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100636482; called by muse, mutect2, varscan2
- TRIM46 | c.336A>T p.T112= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs754624779, COSV99825820; called by muse, mutect2, varscan2
- TRMT61A | c.180C>T p.C60= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs755843586, COSV54568462; called by muse, mutect2, varscan2
- TSPYL6 | c.591C>T p.N197= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1300159615, COSV100336178; called by muse, mutect2, varscan2
- TTC13 | c.972G>A p.G324= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV64168330; called by muse, mutect2, varscan2
- USP38 | c.957T>C p.N319= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100189020; called by muse, mutect2, varscan2
- USP54 | c.2160C>A p.S720= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100160811; called by muse, mutect2, varscan2
- VPS13A | c.6834T>C p.G2278= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs113316143, COSV62429797; called by muse, mutect2, varscan2
- VWA8 | c.1047T>C p.H349= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99863417; called by muse, mutect2, varscan2
- WWC3 | c.2286G>A p.A762= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs747484404, COSV101080898; called by muse, mutect2, varscan2
- WWOX | c.678G>A p.E226= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs750905852, COSV101282827; ClinVar: likely benign; called by muse, mutect2, varscan2
- XIRP2 | c.222C>T p.C74= (on ENST00000628543; = p.C249= on NM_152381.6) | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs778378248, COSV54695947; called by muse, mutect2, varscan2
- XRCC3 | c.507G>A p.L169= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs766394376, COSV100572266; called by muse, mutect2, varscan2
- ZAN | c.1317C>T p.S439= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV100768954; called by muse, mutect2, varscan2
- ZBTB38 | c.3099C>T p.T1033= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs750805955, COSV100375150; called by muse, mutect2, varscan2
- ZNF208 | c.1122C>T p.C374= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs565329409, COSV68100222; called by muse, mutect2
- ZNF488 | c.309G>A p.T103= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as rs376864541; called by muse, mutect2
- ZNF575 | c.444G>T p.P148= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100045330; called by muse, mutect2, varscan2
- ZNF761 | c.186G>A p.A62= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs759096681, COSV61889749; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851223 C>T | 3'Flank (SNP) | VAF 21/56 reads (38%) | catalogued as rs774121330; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851927 del A | 3'Flank (DEL) | VAF 8/20 reads (40%) | catalogued as rs760456851; called by mutect2, varscan2
- CABLES1 | c.845+19340del | Intron (DEL) | VAF 8/37 reads (22%) | catalogued as COSV56932004; called by mutect2, pindel, varscan2
- CTNS | c.*258G>T | 3'UTR (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99250922; called by muse, mutect2
- DNM3 | c.1689+7542C>T | Intron (SNP) | VAF 50/129 reads (39%) | catalogued as COSV100797713; called by muse, mutect2, varscan2
- ELMOD3 | c.943+19G>T | Intron (SNP) | VAF 27/64 reads (42%) | catalogued as COSV99809243; called by muse, mutect2, varscan2
- HERC2P3 | n.1817G>A | RNA (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- HERC2P3 | n.23A>G | RNA (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- KIAA0930 | c.853-930del | Intron (DEL) | VAF 12/25 reads (48%) | catalogued as rs764079139; called by mutect2, pindel, varscan2
- LRRTM1 | c.-1A>T | 5'UTR (SNP) | VAF 37/73 reads (51%) | catalogued as COSV99701573; called by muse, mutect2, varscan2
- MACF1 | c.16491+560dup | Intron (INS) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- MBNL2 | c.994+1355C>A | Intron (SNP) | VAF 25/73 reads (34%) | catalogued as COSV100600198; called by muse, mutect2, varscan2
- MIR492 | n.111C>T | RNA (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- MRPS12 | c.*1C>T | 3'UTR (SNP) | VAF 28/90 reads (31%) | catalogued as rs773420592, COSV99671038; called by muse, mutect2, varscan2
- NXF5 | n.1505G>A | RNA (SNP) | VAF 99/217 reads (46%) | catalogued as rs772277778, COSV99533980; called by muse, mutect2, varscan2
- OBSCN | c.11660-2060C>T | Intron (SNP) | VAF 23/59 reads (39%) | catalogued as COSV99470887; called by muse, mutect2, varscan2
- SMARCB1 | c.363-2340C>A | Intron (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99574645, COSV99575478; called by muse, mutect2, varscan2
- SNORD116-29 | n.23del | RNA (DEL) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
- ZKSCAN4 | c.-1A>G | 5'UTR (SNP) | VAF 5/10 reads (50%) | catalogued as COSV101043316; called by muse, mutect2, varscan2
